Somatic mutation profile of tumor specimen TCGA-VM-A8CB-01A (aliquot TCGA-VM-A8CB-01A-11D-A36O-08) from TCGA case TCGA-VM-A8CB, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.8 years (12,340 days).
Specimen TCGA-VM-A8CB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d57a971-ef4a-4fd8-9275-610ac33328be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8CB-10A (Blood Derived Normal), aliquot TCGA-VM-A8CB-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97a6286f-70a5-4f8d-b541-89e849bb23d2

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/97 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRA3 | c.2830A>G p.R944G | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV99293315; called by muse, mutect2, varscan2
- ARHGAP31 | c.2873A>G p.K958R | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV99957165; called by muse, varscan2
- CCL11 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100005601; called by muse, mutect2, varscan2
- CIC | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50709550, COSV99359625; called by muse, mutect2, varscan2
- CYP39A1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99242329; called by muse, mutect2, varscan2
- EVPL | c.5847G>T p.R1949S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs1398936018, COSV100044587; called by muse, mutect2, varscan2
- FLNC | c.6367C>T p.P2123S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100368152, COSV57958841; called by muse, mutect2, varscan2
- GRIK5 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV99490603; called by muse, mutect2, varscan2
- IGBP1 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100642978; called by muse, mutect2, varscan2
- ITGA4 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99276357; called by muse, mutect2
- KIF16B | c.1643T>A p.M548K | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.889); catalogued as rs375823359; called by muse, mutect2, varscan2
- KIF6 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs757976747, COSV54667341; called by muse, mutect2, varscan2
- MEP1A | c.158A>T p.D53V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100042759; called by muse, mutect2, varscan2
- MLPH | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99222240; called by muse, mutect2, varscan2
- MYH3 | c.1533C>A p.F511L | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV56863226; called by muse, mutect2, varscan2
- NEFM | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV99647211, COSV99647322; called by muse, mutect2, varscan2
- PADI1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs142259163; called by muse, mutect2, varscan2
- RSRC1 | c.369G>C p.R123S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.978); catalogued as COSV99906252; called by muse, mutect2, varscan2
- USP26 | c.1754G>C p.S585T | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.911); catalogued as rs758415574, COSV100896645; called by muse, mutect2, varscan2
- FUBP1 | c.1538_1539del p.A513Vfs*11 | Frame Shift Del (DEL) | VAF 19/32 reads (59%) | called by mutect2, pindel, varscan2
- ATXN2 | c.3402G>A p.A1134= (on ENST00000550104; = p.A974= on NM_002973.4) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs964446609, COSV66483086; called by muse, mutect2, varscan2
- EIF3B | c.990A>G p.E330= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as COSV100703718; called by muse, mutect2, varscan2
- MAP2K6 | c.24G>A p.K8= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as COSV100765084, COSV63008243; called by muse, mutect2
- VPS36 | c.912T>A p.R304= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100955207; called by muse, mutect2, varscan2
